Somatic mutation profile of tumor specimen 0DBM2N from CCDI case PBBLBT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,618 days).
Specimen 0DBM2N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fc219b7-7e39-4d38-b35a-6bf28bda8d46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBM2U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19d321c8-e2c1-434a-9b52-24e2d824229a

The open-access MAF lists 19 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, 3'UTR 2, Intron 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.2851C>T p.L951F | Missense Mutation (SNP) | VAF 89/410 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as rs147178336; called by muse, mutect2, varscan2
- PTCH1 | c.1350del p.A451Pfs*5 | Frame Shift Del (DEL) | VAF 342/385 reads (89%) | catalogued as COSV59465564; called by mutect2, varscan2
- SMOC1 | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 134/952 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777501953, COSV62760091; called by muse, mutect2, varscan2
- ARHGEF2 | c.2464C>G p.R822G (on ENST00000361247 / NM_001162383.2; = p.R794G on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 101/1006 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2
- LAMB1 | c.676+1G>A p.X226_splice | Splice Site (SNP) | VAF 199/1219 reads (16%) | called by muse, mutect2, varscan2
- MICU3 | c.121C>G p.R41G | Missense Mutation (SNP) | VAF 131/711 reads (18%) | SIFT tolerated, low confidence (0.41); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2652A>G p.I884M | Missense Mutation (SNP) | VAF 37/1404 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2
- NXF1 | c.1087G>T p.D363Y | Missense Mutation (SNP) | VAF 128/940 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZC3H11B | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by mutect2, varscan2
- ZDHHC8 | c.1184T>G p.V395G | Missense Mutation (SNP) | VAF 137/597 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CRYBG2 | c.4113C>T p.F1371= | Silent (SNP) | VAF 98/800 reads (12%) | catalogued as rs537765169; called by muse, mutect2, varscan2
- FNDC3A | c.1578A>C p.T526= (on ENST00000492622 / NM_001079673.2; = p.T470= on NM_014923.5) | Silent (SNP) | VAF 64/1088 reads (6%) | called by muse, mutect2
- HRH4 | c.414C>T p.A138= | Silent (SNP) | VAF 104/892 reads (12%) | catalogued as rs753573404; called by muse, varscan2
- MID2 | c.594T>C p.H198= | Silent (SNP) | VAF 80/498 reads (16%) | called by muse, mutect2, varscan2
- ZC3H11B | c.246C>T p.F82= | Silent (SNP) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- CCDC81 | c.1471-11C>G | Intron (SNP) | VAF 92/330 reads (28%) | called by mutect2, varscan2
- KHDRBS2 | c.*93del | 3'UTR (DEL) | VAF 10/39 reads (26%) | catalogued as rs960944866; called by mutect2, varscan2
- SENP6 | c.2288+11A>T | Intron (SNP) | VAF 29/694 reads (4%) | called by muse, mutect2
- SPAG17 | c.*452T>A | 3'UTR (SNP) | VAF 52/302 reads (17%) | called by muse, mutect2, varscan2
